Somatic mutation profile of tumor specimen TCGA-WB-A81Q-01A (aliquot TCGA-WB-A81Q-01A-11D-A35I-08) from TCGA case TCGA-WB-A81Q, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 45.0 years (16,422 days).
Specimen TCGA-WB-A81Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d03aee16-2661-4275-8db7-6ab94609c35a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81Q-10A (Blood Derived Normal), aliquot TCGA-WB-A81Q-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54a75df8-fa6b-48f8-9956-f56cdc7686d3

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PSMD1 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs201274207, COSV58078357; called by muse, mutect2, varscan2
- SHROOM3 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs761718159; called by muse, mutect2, varscan2
- TRPC6 | c.468A>C p.E156D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as COSV100723657; called by muse, mutect2, varscan2
- JOSD2 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACROH2A1 | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MED13L | c.3368T>G p.F1123C | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MGAT4A | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.996); called by muse, mutect2
- MLLT1 | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MMP8 | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.034); called by muse, mutect2
- NEB | c.11354A>G p.D3785G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SETD2 | c.4538A>T p.E1513V | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2
- SLC22A5 | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SPHKAP | c.4295A>G p.E1432G | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPTA1 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2
- VPS8 | c.3382C>T p.Q1128* (on ENST00000625842 / NM_001349294.1; = p.Q1126* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4053G>A p.V1351= | Silent (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- CEACAM6 | c.663G>A p.A221= | Silent (SNP) | VAF 102/239 reads (43%) | catalogued as rs782339128; called by muse, mutect2, varscan2
- HEBP2 | c.114T>C p.Y38= | Silent (SNP) | VAF 70/148 reads (47%) | catalogued as rs1403742525; called by muse, mutect2, varscan2
- KCNC1 | c.204G>C p.L68= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV56392340; called by muse, mutect2, varscan2
- OR8I2 | c.48A>G p.G16= | Silent (SNP) | VAF 92/220 reads (42%) | called by muse, mutect2, varscan2
